Somatic mutation profile of tumor specimen 0DUFE5 from CCDI case PBCKSG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Desmoplastic small round cell tumor; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 20.2 years (7,393 days).
Specimen 0DUFE5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c87f8289-2f6f-4827-8d0c-723f0effd16e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUFD9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f43cc59f-3f90-46e4-80ba-c11050c4f7df

The open-access MAF lists 19 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, Intron 3, Splice Site 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX27 | c.2362T>G p.S788A | Missense Mutation (SNP) | VAF 286/503 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); catalogued as rs780660531; called by muse, mutect2, varscan2
- FAT2 | c.9563G>A p.R3188H | Missense Mutation (SNP) | VAF 273/968 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as rs1292734630, COSV55831209; called by muse, mutect2, varscan2
- PIWIL1 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 346/622 reads (56%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as rs1225500017, COSV55346646, COSV99807047; called by muse, mutect2, varscan2
- PRPF8 | c.5539G>A p.A1847T | Missense Mutation (SNP) | VAF 92/448 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV59263729; called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 34/792 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- PABPC4L | c.624C>G p.D208E | Missense Mutation (SNP) | VAF 35/881 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PPP4R3A | c.521T>A p.L174Q | Missense Mutation (SNP) | VAF 29/593 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SENP7 | c.2752-1G>A p.X918_splice | Splice Site (SNP) | VAF 137/472 reads (29%) | called by muse, mutect2, varscan2
- SLC4A5 | c.1026A>T p.R342S | Missense Mutation (SNP) | VAF 106/537 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- USP15 | c.2705G>A p.G902E (on ENST00000280377 / NM_001351159.2; = p.G873E on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/486 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.333); called by muse, varscan2
- GZF1 | c.78C>T p.L26= | Silent (SNP) | VAF 335/1325 reads (25%) | called by muse, mutect2, varscan2
- PTPN5 | c.180T>A p.P60= | Silent (SNP) | VAF 307/558 reads (55%) | called by mutect2, varscan2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 36/946 reads (4%) | called by muse, mutect2
- ZNF672 | c.564G>A p.R188= | Silent (SNP) | VAF 224/750 reads (30%) | called by muse, mutect2, varscan2
- GCNT2 | c.925+30C>T | Intron (SNP) | VAF 18/198 reads (9%) | catalogued as rs1263994820; called by muse, mutect2
- GRIP2 | c.1003+94C>G | Intron (SNP) | VAF 42/98 reads (43%) | called by muse, mutect2, varscan2
- LINC02860 | n.1184C>T | RNA (SNP) | VAF 61/276 reads (22%) | called by muse, mutect2, varscan2
- OBSL1 | c.3226+79C>T | Intron (SNP) | VAF 10/58 reads (17%) | called by muse, mutect2
- RBL1 | c.-15G>A | 5'UTR (SNP) | VAF 58/385 reads (15%) | called by muse, mutect2, varscan2
